Somatic mutation profile of tumor specimen ALCH-B3CI-TTP1-A (aliquot ALCH-B3CI-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3CI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 38.7 years (14,126 days).
Specimen ALCH-B3CI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7833c586-c4f5-435b-865a-ca287ee16b8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3CI-NB1-A (Blood Derived Normal), aliquot ALCH-B3CI-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c8d3ad2-390e-4be4-8377-02513c631a69

The open-access MAF lists 213 somatic variants for this specimen: 146 protein-altering or splice-affecting, 40 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 40, Intron 12, Nonsense Mutation 11, RNA 5, Splice Region 4, 5'UTR 4, Frame Shift Del 3, 3'UTR 3, 5'Flank 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1026+2T>G p.X342_splice | Splice Site (SNP) | VAF 12/81 reads (15%) | hotspot (GDC flag); catalogued as rs1114167624, COSV100910531, COSV64291630; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV60619911; called by muse, mutect2
- ADAMTSL3 | c.4552A>T p.T1518S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54474179; called by muse, mutect2, varscan2
- ADGRB1 | c.4172G>A p.R1391H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs765352565; called by muse, mutect2, varscan2
- AKAP3 | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as rs1309107057; called by muse, mutect2, varscan2
- ALDH3A2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs745645947; called by muse, mutect2
- AMIGO2 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56974644; called by muse, mutect2, varscan2
- ARAP1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs375146072; called by muse, mutect2, varscan2
- ASXL1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748649917, COSV60102669; called by muse, mutect2, varscan2
- BRD7 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325340063, COSV67158465, COSV67158877; called by muse, mutect2
- CNTNAP5 | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1171362907, COSV70494207; called by muse, mutect2
- CSNK2A3 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242142108; called by muse, mutect2, varscan2
- CYP11B1 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.673); catalogued as COSV99454264; called by muse, mutect2, varscan2
- DCHS1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as rs1332520980; called by muse, mutect2, varscan2
- DEPDC5 | c.3263C>T p.S1088L (on ENST00000400246; = p.S1157L on NM_014662.5) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as rs376487148, COSV99836702; ClinVar: uncertain significance; called by muse, mutect2
- FASN | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs143739434; called by muse, mutect2
- FER1L5 | c.2857G>A p.E953K (on ENST00000623019; = p.E960K on NM_001293083.2) | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.506); catalogued as rs1259640966; called by muse, mutect2, varscan2
- GABRB3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs572427454, COSV54661748; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXD10 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99983012; called by muse, mutect2, varscan2
- IHO1 | c.1423T>C p.Y475H | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1454531463; called by muse, mutect2, varscan2
- LAMA2 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.219); catalogued as rs867108117; called by muse, mutect2, varscan2
- LIMCH1 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1363143826; called by muse, mutect2
- LRRTM4 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69140170; called by muse, mutect2, varscan2
- LYST | c.10681C>G p.Q3561E | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1041137098; called by muse, mutect2
- MAP1B | c.5427G>T p.E1809D | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV99702678; called by muse, mutect2, varscan2
- MBD5 | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1478302810; called by muse, mutect2, varscan2
- MMP16 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs373603451; called by muse, mutect2, varscan2
- MYH1 | c.5584C>A p.R1862S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99875262; called by muse, mutect2, varscan2
- MYL6B | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs768327872; called by muse, mutect2, varscan2
- NAA15 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV56723376; called by muse, mutect2, varscan2
- NAGS | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs746624443; called by muse, mutect2, varscan2
- NDUFC1 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 22/134 reads (16%) | catalogued as rs201035643; called by muse, mutect2, varscan2
- NUCB1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs1417693548; called by muse, varscan2
- OBSL1 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as rs1412249802; called by muse, mutect2, varscan2
- OR5M11 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV73141676; called by muse, mutect2, varscan2
- OTOGL | c.5206G>A p.D1736N (on ENST00000547103; = p.D1727N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100087338; called by muse, mutect2, varscan2
- OTX2 | c.575C>T p.S192L (on ENST00000408990 / NM_172337.3; = p.S200L on NM_021728.4) | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100257712; called by muse, mutect2, varscan2
- P2RY8 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374787831; called by muse, mutect2, varscan2
- PCDH11X | c.3308G>A p.R1103H | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764386893, COSV53481979, COSV53499828; called by muse, mutect2, varscan2
- PCDH15 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.609); catalogued as COSV57321178; called by muse, mutect2, varscan2
- PCDHB5 | c.1975G>T p.V659L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.265); catalogued as rs1399173791; called by muse, mutect2, varscan2
- PDE1C | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV58516534; called by muse, mutect2
- PGM1 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.614); catalogued as COSV64300092; called by muse, mutect2
- PKHD1L1 | c.3390del p.V1131Lfs*10 | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | catalogued as COSV65747190; called by mutect2, pindel, varscan2
- POLR3A | c.3718G>A p.G1240S | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1003620056, CM1411441, COSV100965612; called by muse, mutect2, varscan2
- PPP4R3B | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.403); catalogued as COSV55403867; called by muse, mutect2
- PRLR | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV51495842; called by muse, mutect2, varscan2
- PSMB9 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV66399502; called by mutect2, varscan2
- PTBP1 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.781); catalogued as rs757290221; called by muse, mutect2, varscan2
- RANBP2 | c.6160G>C p.E2054Q | Missense Mutation (SNP) | VAF 43/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51698127; called by muse, mutect2, varscan2
- RRAS2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56329700, COSV56329705; called by muse, mutect2, varscan2
- SELENOS | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs540535730; called by muse, mutect2, varscan2
- SEMA5A | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766020101; called by muse, mutect2, varscan2
- SLC4A10 | c.1494G>C p.W498C (on ENST00000446997 / NM_001354461.2; = p.W468C on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV55777903; called by muse, mutect2, varscan2
- SLC8A3 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766048508, COSV63519397, COSV63528204; called by muse, mutect2, varscan2
- TRIM68 | c.1110G>A p.W370* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs778194276; called by muse, mutect2, varscan2
- TYRP1 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as rs1471257225; called by muse, mutect2, varscan2
- UNC13A | c.4379C>T p.A1460V | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as rs1237421915, COSV99407858; called by muse, mutect2, varscan2
- UPB1 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764880194; called by muse, mutect2, varscan2
- VCAN | c.7754C>A p.P2585H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54096471; called by mutect2, varscan2
- ZNF519 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 19/219 reads (9%) | catalogued as COSV101644741; called by muse, mutect2
- ZNF729 | c.2710G>T p.A904S | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs746060288; called by muse, mutect2, varscan2
- ACMSD | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); called by muse, mutect2
- ADCY5 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- AK7 | c.817C>G p.H273D | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AQP12A | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BICC1 | c.1050T>C p.G350= | Splice Region (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- C1RL | c.444G>C p.K148N | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, varscan2
- CAPN1 | c.1888G>C p.D630H | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC33 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CFP | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CGGBP1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CNOT1 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- COL1A2 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- CUL7 | c.2893G>C p.E965Q | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CYP2W1 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2
- DAAM1 | c.1894G>C p.D632H | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDX42 | c.2390G>T p.R797L | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); called by muse, mutect2
- DHPS | c.823T>C p.C275R | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH1 | c.12451G>C p.E4151Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH5 | c.2669T>A p.V890E | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJB1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.117); called by muse, mutect2
- DST | c.2671C>T p.P891S (on ENST00000361203 / NM_001374722.1; = p.P565S on NM_001723.6) | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EFCAB8 | c.2628C>G p.I876M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ELFN2 | c.2304G>T p.K768N | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- EVPLL | c.371G>T p.W124L | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EVPLL | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- FAM229B | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FKBP6 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 58/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FLG | c.5921C>G p.S1974C | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2
- GANC | c.1365G>T p.Q455H | Missense Mutation (SNP) | VAF 24/196 reads (12%) | PolyPhen benign (0.015); called by muse, varscan2
- GAS1 | c.533G>C p.R178P | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GAS1 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- GASK1B | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLM1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPN3 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- HASPIN | c.1467G>T p.K489N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCFC1 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HLA-C | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IZUMO3 | c.17T>A p.L6* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | called by mutect2, varscan2
- KCNMB2 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRIQ1 | c.4463C>G p.P1488R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- M1AP | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MICAL2 | c.5838C>G p.F1946L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- MPEG1 | c.1951G>A p.G651S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MS4A14 | c.1850del p.P617Rfs*61 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- MTERF2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYRFL | c.2642C>A p.A881E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NCKAP1 | c.3124G>T p.A1042S | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NEXMIF | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- NLRP3 | c.1553T>A p.F518Y | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4S2 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR9G1 | c.578del p.G193Afs*5 | Frame Shift Del (DEL) | VAF 12/166 reads (7%) | called by mutect2, pindel
- OTX2 | c.574T>C p.S192P (on ENST00000408990 / NM_172337.3; = p.S200P on NM_021728.4) | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PCDH11Y | c.1379C>T p.S460F (on ENST00000400457 / NM_032973.2; = p.S449F on NM_032971.3) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PCDHA3 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCDHA7 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PCDHAC1 | c.2838G>T p.K946N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POU2F1 | c.162C>T p.V54= (on ENST00000541643 / NM_001365848.1; = p.V77= on NM_002697.4) | Splice Region (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- PPP4R3C | c.2058G>T p.M686I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB3A | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASGRP1 | c.36-6C>A | Splice Region (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- RMND5A | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ROS1 | c.3098C>A p.S1033* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- SBSN | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SELPLG | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 11/233 reads (5%) | called by muse, mutect2
- SLC36A4 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO5A1 | c.2433A>T p.Q811H | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SMARCA4 | c.222G>A p.K74= | Splice Region (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- SMIM6 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATC1L | c.820T>A p.F274I (on ENST00000291672 / NM_001142854.2; = p.F120I on NM_032261.5) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2
- TDRD3 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TJP1 | c.4936G>T p.V1646L | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TMEM131 | c.3208C>G p.P1070A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM132B | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TMEM160 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIQK | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- USP2 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR11 | c.3242G>T p.R1081L | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WDR12 | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- WDR19 | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); called by muse, mutect2
- ZNF205 | c.1611G>C p.M537I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF322 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZNF492 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- ZNF627 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF845 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- ABCC1 | c.2826G>A p.E942= | Silent (SNP) | VAF 38/250 reads (15%) | called by muse, mutect2, varscan2
- ANKRD13A | c.693C>G p.V231= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- AP3B1 | c.102C>T p.F34= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as rs1460618374, COSV54884964, COSV54895344; called by muse, varscan2
- APOB | c.1623G>A p.Q541= | Silent (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- ARHGAP25 | c.210G>A p.L70= (on ENST00000409202 / NM_001007231.3; = p.L63= on NM_014882.3) | Silent (SNP) | VAF 48/244 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.2457G>T p.L819= | Silent (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- ATP13A5 | c.1155G>C p.L385= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs141862218; called by muse, mutect2
- C17orf75 | c.495C>T p.F165= | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- CAB39L | c.939G>A p.T313= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs1215317988, COSV100759660; called by muse, mutect2
- CLTA | c.63C>T p.N21= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- DISC1 | c.1164C>T p.I388= | Silent (SNP) | VAF 32/257 reads (12%) | catalogued as COSV54407072; called by muse, mutect2, varscan2
- ENKD1 | c.294G>A p.K98= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV54667736; called by muse, mutect2, varscan2
- GPRC6A | c.1092C>T p.C364= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs144049198; called by muse, mutect2, varscan2
- KCNN1 | c.39G>T p.P13= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs1414071066; called by muse, mutect2, varscan2
- MAU2 | c.567C>A p.L189= | Silent (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- MAU2 | c.1513C>T p.L505= | Silent (SNP) | VAF 21/173 reads (12%) | called by muse, mutect2, varscan2
- MPDZ | c.5811T>C p.S1937= (on ENST00000319217 / NM_001330637.2; = p.S1908= on NM_003829.5) | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- MRPL10 | c.711C>T p.I237= | Silent (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
- MYO3B | c.2598G>A p.T866= | Silent (SNP) | VAF 15/215 reads (7%) | catalogued as rs764009844; called by muse, mutect2
- OLFM3 | c.879T>C p.T293= (on ENST00000338858 / NM_001288821.1; = p.T273= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/174 reads (18%) | catalogued as COSV58799877; called by muse, mutect2, varscan2
- OR2T35 | c.846C>A p.T282= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as rs1425176132; called by muse, mutect2, varscan2
- PCDHB7 | c.1809G>A p.S603= | Silent (SNP) | VAF 40/383 reads (10%) | catalogued as rs782548110; called by muse, mutect2, varscan2
- PDZD2 | c.3342G>A p.L1114= | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- PLD4 | c.6G>A p.L2= | Silent (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- PLEKHG7 | c.1611C>A p.L537= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- PPARG | c.624C>T p.I208= (on ENST00000287820 / NM_015869.5; = p.I178= on NM_005037.7) | Silent (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- RELN | c.4086A>T p.T1362= | Silent (SNP) | VAF 56/264 reads (21%) | called by muse, mutect2, varscan2
- RYR1 | c.11529C>G p.L3843= | Silent (SNP) | VAF 22/532 reads (4%) | called by muse, mutect2
- RYR3 | c.6045C>A p.I2015= | Silent (SNP) | VAF 37/233 reads (16%) | catalogued as COSV66797709; called by muse, mutect2, varscan2
- SLITRK6 | c.1362C>T p.T454= | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- TBPL2 | c.921G>A p.L307= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs1043002400; called by muse, mutect2
- TBX3 | c.219G>A p.E73= | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV99050477; called by muse, mutect2, varscan2
- TENM2 | c.138G>A p.L46= | Silent (SNP) | VAF 68/356 reads (19%) | called by muse, mutect2, varscan2
- TMEM200C | c.598C>T p.L200= | Silent (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1515G>C p.L505= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV61454611; called by muse, mutect2, varscan2
- VPS45 | c.396G>A p.V132= | Silent (SNP) | VAF 36/189 reads (19%) | called by muse, mutect2, varscan2
- VSIG4 | c.468C>A p.P156= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- VSTM2A | c.102G>A p.R34= | Silent (SNP) | VAF 57/272 reads (21%) | called by muse, mutect2, varscan2
- WBP2NL | c.681A>G p.P227= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV60921094; called by muse, mutect2
- ZNF484 | c.1899G>A p.E633= | Silent (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- AL139327.1 | n.286G>T | RNA (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3733A>G | Intron (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- ATP2A3 | c.3068+9C>G | Intron (SNP) | VAF 32/171 reads (19%) | called by muse, mutect2, varscan2
- BBS4 | c.*199C>A | 3'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- C1QTNF9 | c.-17A>C | 5'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3794G>C | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as COSV104376420; called by muse, mutect2, varscan2
- CCDC116 | c.1203+45C>A | Intron (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- COL7A1 | c.7105-41G>A | Intron (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- DCX | c.-22-522T>A | Intron (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- DNAH8 | c.-235G>C | 5'UTR (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- EPB41L3 | c.*59G>C | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- FANCA | c.893+26G>C | Intron (SNP) | VAF 67/433 reads (15%) | catalogued as rs1174568028; called by muse, mutect2, varscan2
- HBB | c.-13T>A | 5'UTR (SNP) | VAF 43/283 reads (15%) | catalogued as COSV100092889, COSV100092892; called by muse, mutect2, varscan2
- LINC00293 | n.489G>T | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- LINC01558 | n.306C>T | RNA (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- LRRK2 | c.3777+17C>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- MIR4771-1 | chr2:87193567 A>G | 5'Flank (SNP) | VAF 31/186 reads (17%) | called by muse, mutect2, varscan2
- NME9 | c.91+394C>A | Intron (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- OTX1 | c.98-13C>G | Intron (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- RSRC2 | c.-19G>A | 5'UTR (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- SHISA8 | chr22:41909875 T>C | 3'Flank (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2
- SSPOP | n.4135C>A | RNA (SNP) | VAF 42/248 reads (17%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133567975 C>G | 5'Flank (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- VAV2 | c.380+11C>T | Intron (SNP) | VAF 12/92 reads (13%) | catalogued as rs200420003; called by muse, mutect2, varscan2
- XXYLT1 | c.785+34300C>G | Intron (SNP) | VAF 34/271 reads (13%) | called by muse, mutect2, varscan2
- ZNF204P | n.978G>A | RNA (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- ZNF99 | c.*603A>T | 3'UTR (SNP) | VAF 31/137 reads (23%) | catalogued as rs750181259; called by muse, varscan2
